Somatic mutation profile of tumor specimen ALCH-AEJU-TTP1-A (aliquot ALCH-AEJU-TTP1-A-1-0-D-A618-36) from ALCHEMIST case ALCH-AEJU, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 58.0 years (21,202 days).
Specimen ALCH-AEJU-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 705c9a10-ecdd-40d4-a61c-79d132211d7a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEJU-NB1-A (Blood Derived Normal), aliquot ALCH-AEJU-NB1-A-1-0-D-A618-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/55226ba9-f4a6-4568-b0f9-63e95d458c70

The open-access MAF lists 291 somatic variants for this specimen: 208 protein-altering or splice-affecting, 52 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 181, Silent 52, Nonsense Mutation 15, Intron 11, Splice Site 9, 3'UTR 6, 5'UTR 5, 3'Flank 4, 5'Flank 3, RNA 2, Splice Region 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS20 | c.307G>T p.G103C | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.953); catalogued as COSV101239254; called by muse, mutect2
- ADARB2 | c.1754T>C p.V585A | Missense Mutation (SNP) | VAF 9/170 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as rs1433594204; called by muse, mutect2
- ADGRG4 | c.7354C>A p.P2452T | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54956055; called by muse, mutect2
- ARHGAP11A | c.2507C>T p.T836I | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1310077034; called by muse, mutect2
- CADPS | c.1793A>T p.E598V | Missense Mutation (SNP) | VAF 14/270 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99338678; called by muse, mutect2
- CAMTA1 | c.627G>C p.W209C | Missense Mutation (SNP) | VAF 15/268 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57927402; called by muse, mutect2
- CEMIP | c.344C>A p.P115H | Missense Mutation (SNP) | VAF 41/553 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as COSV99587087; called by muse, mutect2
- CNGA3 | c.1861G>A p.A621T | Missense Mutation (SNP) | VAF 60/649 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.019); catalogued as rs546831778, COSV55624691; called by muse, mutect2
- CNTNAP5 | c.2673C>A p.D891E | Missense Mutation (SNP) | VAF 24/502 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1313414945; called by muse, mutect2
- COL2A1 | c.2050-1G>A p.X684_splice | Splice Site (SNP) | VAF 33/505 reads (7%) | catalogued as CS052398; called by muse, mutect2
- CSMD3 | c.10760G>T p.G3587V (on ENST00000297405 / NM_001363185.1; = p.G3418V on NM_052900.3) | Missense Mutation (SNP) | VAF 17/221 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1001474038; called by muse, mutect2
- CYFIP2 | c.2233G>T p.V745F (on ENST00000616178 / NM_001291722.2; = p.V720F on NM_014376.4) | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.932); catalogued as COSV59030435; called by muse, mutect2
- DCAF12L2 | c.836C>A p.A279E | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV100758530; called by muse, mutect2, varscan2
- DGKI | c.1081G>T p.G361C | Missense Mutation (SNP) | VAF 12/159 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.848); catalogued as COSV99937829; called by muse, mutect2
- DMXL2 | c.1744G>T p.E582* | Nonsense Mutation (SNP) | VAF 32/362 reads (9%) | catalogued as COSV51854082, COSV51854384; called by muse, mutect2
- DPYS | c.1451C>T p.T484I | Missense Mutation (SNP) | VAF 24/387 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs939912222; called by muse, mutect2
- EBF3 | c.418G>A p.V140I | Missense Mutation (SNP) | VAF 28/328 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62480423; called by muse, mutect2
- EDN3 | c.412G>T p.G138C | Missense Mutation (SNP) | VAF 21/344 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV61107205; called by muse, mutect2
- FAM170B | c.733C>T p.R245W | Missense Mutation (SNP) | VAF 23/341 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as rs181408191; called by muse, mutect2
- GRIN2A | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 20/364 reads (5%) | catalogued as rs1555455713; called by muse, mutect2
- HAO1 | c.251G>T p.R84L | Missense Mutation (SNP) | VAF 26/238 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as COSV66491567; called by muse, mutect2, varscan2
- HNRNPUL2 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs921658677; called by muse, mutect2
- LILRB4 | c.35-1G>T p.X12_splice | Splice Site (SNP) | VAF 20/288 reads (7%) | catalogued as COSV54404907, COSV99554249; called by muse, mutect2
- LRRTM4 | c.397C>A p.P133T | Missense Mutation (SNP) | VAF 12/278 reads (4%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.581); catalogued as COSV69142029; called by muse, mutect2
- MAGEC3 | c.1841G>T p.R614I | Missense Mutation (SNP) | VAF 12/185 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV68924424; called by muse, mutect2
- MYH2 | c.1234G>T p.E412* | Nonsense Mutation (SNP) | VAF 36/600 reads (6%) | catalogued as rs141292639; called by muse, mutect2
- NAV3 | c.2860C>G p.H954D | Missense Mutation (SNP) | VAF 14/298 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV57106406; called by muse, mutect2
- NEUROG1 | c.634C>A p.P212T | Missense Mutation (SNP) | VAF 12/366 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as COSV100130877, COSV100130878; called by muse, mutect2
- NLRP3 | c.725C>A p.A242E | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs1041601343, COSV100275439; called by muse, mutect2, varscan2
- OCA2 | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 32/414 reads (8%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.003); catalogued as rs965907142; called by muse, mutect2
- OR10AG1 | c.295G>T p.G99* | Nonsense Mutation (SNP) | VAF 10/74 reads (14%) | catalogued as COSV56633863; called by mutect2, varscan2
- OR10G7 | c.583G>T p.E195* | Nonsense Mutation (SNP) | VAF 71/445 reads (16%) | catalogued as COSV57868973; called by muse, varscan2
- OR1N2 | c.606C>G p.I202M | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.178); catalogued as COSV65460782, COSV65460829; called by muse, mutect2
- OR52E4 | c.853C>A p.P285T | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57625284; called by muse, mutect2, varscan2
- OTC | c.622del p.A208Qfs*22 | Frame Shift Del (DEL) | VAF 62/592 reads (10%) | catalogued as CM961056, COSV50001314; called by mutect2, pindel, varscan2
- OTULIN | c.940G>C p.E314Q | Missense Mutation (SNP) | VAF 21/340 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52506989; called by muse, mutect2
- PAGE5 | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 22/412 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.423); catalogued as COSV99215824; called by muse, mutect2
- PAX3 | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 44/732 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100399267; called by muse, mutect2
- PCDH15 | c.5266C>A p.P1756T | Missense Mutation (SNP) | VAF 24/334 reads (7%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV100227106; called by muse, mutect2
- PLB1 | c.4003-1G>A p.X1335_splice | Splice Site (SNP) | VAF 21/199 reads (11%) | catalogued as COSV59837430; called by muse, mutect2, varscan2
- PPFIA2 | c.484C>A p.Q162K | Missense Mutation (SNP) | VAF 26/306 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV61037577; called by muse, mutect2
- PTGDR | c.128G>T p.R43L | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as COSV100035596; called by muse, mutect2
- RELN | c.6157C>T p.L2053F | Missense Mutation (SNP) | VAF 63/666 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs779142703; ClinVar: uncertain significance; called by muse, mutect2
- RSPO2 | c.159C>A p.S53R | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as COSV52645959; called by muse, mutect2
- RYR1 | c.2551G>T p.V851L | Missense Mutation (SNP) | VAF 27/286 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.29); catalogued as rs375669412; called by muse, mutect2
- SCN10A | c.3752C>T p.T1251I | Missense Mutation (SNP) | VAF 21/360 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV71862158; called by muse, mutect2
- SMOC2 | c.1078G>T p.D360Y (on ENST00000356284 / NM_001166412.2; = p.D371Y on NM_022138.3) | Missense Mutation (SNP) | VAF 28/286 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62442006; called by muse, mutect2
- SNRPN | c.698C>A p.P233Q | Missense Mutation (SNP) | VAF 26/435 reads (6%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.725); catalogued as COSV57597139; called by muse, mutect2
- SRGN | c.414G>T p.R138S | Missense Mutation (SNP) | VAF 18/284 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV54345547; called by muse, mutect2
- SV2A | c.334C>T p.R112W | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.586); catalogued as rs587649813, COSV64965202; called by muse, mutect2, varscan2
- TCF4 | c.1915G>T p.E639* | Nonsense Mutation (SNP) | VAF 28/358 reads (8%) | catalogued as rs1555708139; called by muse, mutect2
- TNXB | c.12164G>A p.R4055Q (on ENST00000647633; = p.R3808Q on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/562 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0.006); catalogued as rs376486710; called by muse, mutect2
- TULP4 | c.1691G>T p.R564L | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65575302; called by muse, mutect2
- VAPB | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 23/326 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs886340297; called by muse, mutect2
- ABCA1 | c.2284G>T p.V762F | Missense Mutation (SNP) | VAF 50/594 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ABCC9 | c.3772-2A>T p.X1258_splice | Splice Site (SNP) | VAF 29/253 reads (11%) | called by muse, mutect2, varscan2
- ACAP3 | c.2182G>T p.D728Y | Missense Mutation (SNP) | VAF 30/386 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADAM20 | c.1277T>C p.I426T | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2
- ADAMTS12 | c.4271G>C p.C1424S | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ADAMTS4 | c.823G>T p.G275C | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- ADCY2 | c.2459T>A p.L820Q | Missense Mutation (SNP) | VAF 17/226 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- ADGRA1 | c.71G>T p.C24F | Missense Mutation (SNP) | VAF 33/212 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ADGRL4 | c.1676C>T p.T559I | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- ALG3 | c.844G>T p.A282S | Missense Mutation (SNP) | VAF 30/350 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.049); called by muse, mutect2
- ANXA2 | c.266C>A p.S89* | Nonsense Mutation (SNP) | VAF 32/442 reads (7%) | called by muse, mutect2
- AP1S3 | c.50A>T p.Q17L | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2
- ARFGEF2 | c.2620G>T p.V874L | Missense Mutation (SNP) | VAF 24/400 reads (6%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.77); called by muse, mutect2
- ASB11 | c.193G>T p.D65Y | Missense Mutation (SNP) | VAF 18/312 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ASPM | c.3358G>T p.V1120L | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- B4GALNT3 | c.354C>A p.F118L | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.197); called by muse, mutect2
- BICRA | c.2530C>T p.P844S | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.013); called by muse, mutect2
- CAPN8 | c.907G>T p.E303* | Nonsense Mutation (SNP) | VAF 30/257 reads (12%) | called by muse, mutect2, varscan2
- CD6 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 22/294 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.122); called by muse, mutect2
- CENPE | c.1479+1G>A p.X493_splice | Splice Site (SNP) | VAF 8/83 reads (10%) | called by muse, mutect2
- CES1 | c.956T>G p.L319R | Missense Mutation (SNP) | VAF 20/310 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2
- CFAP46 | c.7811G>T p.G2604V | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2
- CFAP54 | c.1510T>A p.S504T | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0.009); called by muse, mutect2
- CGN | c.1402-2A>T p.X468_splice | Splice Site (SNP) | VAF 31/249 reads (12%) | called by muse, mutect2, varscan2
- COL11A1 | c.2879C>A p.T960N | Missense Mutation (SNP) | VAF 24/464 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); called by muse, mutect2
- COL12A1 | c.4698A>T p.L1566F | Missense Mutation (SNP) | VAF 13/208 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); called by muse, mutect2
- COL22A1 | c.2378T>A p.L793Q | Missense Mutation (SNP) | VAF 31/442 reads (7%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.993); called by muse, mutect2
- CUBN | c.6648C>A p.A2216= | Splice Region (SNP) | VAF 13/264 reads (5%) | called by muse, mutect2
- CXCL10 | c.212A>T p.E71V | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2
- DGLUCY | c.238G>A p.G80S | Missense Mutation (SNP) | VAF 20/318 reads (6%) | SIFT tolerated (0.87); PolyPhen benign (0.007); called by muse, mutect2
- DLAT | c.183G>T p.W61C | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- DSG4 | c.610T>C p.S204P | Missense Mutation (SNP) | VAF 24/262 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, mutect2
- DUOX2 | c.2098A>T p.N700Y | Missense Mutation (SNP) | VAF 33/373 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); called by muse, mutect2
- DZIP1 | c.318C>A p.C106* | Nonsense Mutation (SNP) | VAF 24/368 reads (7%) | called by muse, mutect2
- ECM1 | c.192G>T p.Q64H | Missense Mutation (SNP) | VAF 79/575 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- EIF3A | c.2960C>T p.P987L | Missense Mutation (SNP) | VAF 24/368 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2
- EPB41L2 | c.1357A>T p.S453C | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- EYS | c.4579C>A p.Q1527K | Missense Mutation (SNP) | VAF 12/252 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.057); called by muse, mutect2
- FAM135B | c.949C>A p.L317M | Missense Mutation (SNP) | VAF 42/460 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- FAM135B | c.808C>G p.P270A | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); called by muse, mutect2
- FAM184B | c.1615G>A p.D539N | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2
- FAM186A | c.1384C>A p.H462N | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.174); called by muse, mutect2
- FAM71A | c.459G>T p.L153F | Missense Mutation (SNP) | VAF 24/193 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBN1 | c.3544T>G p.C1182G | Missense Mutation (SNP) | VAF 26/422 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); called by muse, mutect2
- FCGBP | c.8126A>C p.Y2709S | Missense Mutation (SNP) | VAF 46/1846 reads (2%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FCGBP | c.2380G>T p.V794L | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- FOLR3 | c.448T>A p.Y150N | Missense Mutation (SNP) | VAF 8/135 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.046); called by muse, mutect2
- FOSL2 | c.826G>T p.G276C | Missense Mutation (SNP) | VAF 28/374 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.707); called by muse, mutect2
- GABRG2 | c.434T>A p.I145N | Missense Mutation (SNP) | VAF 20/370 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- GABRG3 | c.1289G>T p.R430M | Missense Mutation (SNP) | VAF 30/437 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- GBP5 | c.92T>A p.L31Q | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GPATCH2L | c.829G>A p.V277I | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- GRIPAP1 | c.33G>T p.Q11H | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.995); called by muse, mutect2
- GSPT2 | c.1114C>A p.P372T | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2
- HERC4 | c.928G>T p.V310F | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by muse, mutect2
- HHIPL2 | c.1805+2T>A p.X602_splice | Splice Site (SNP) | VAF 21/144 reads (15%) | called by muse, mutect2, varscan2
- HMGXB4 | c.903A>T p.E301D | Missense Mutation (SNP) | VAF 26/233 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- HOXA2 | c.227G>T p.S76I | Missense Mutation (SNP) | VAF 13/194 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2
- IFT52 | c.924-2A>T p.X308_splice | Splice Site (SNP) | VAF 18/256 reads (7%) | called by muse, mutect2
- IGFN1 | c.2438A>T p.Q813L (on ENST00000295591 / NM_001367841.1; = p.Q3270L on NM_001164586.2) | Missense Mutation (SNP) | VAF 32/188 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- IL1RAPL2 | c.1462G>C p.E488Q | Missense Mutation (SNP) | VAF 14/185 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.09); called by muse, mutect2
- IQSEC3 | c.3155C>A p.S1052Y | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.259); called by muse, mutect2
- ITSN1 | c.2381G>T p.G794V | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KCNH6 | c.2599C>A p.P867T | Missense Mutation (SNP) | VAF 20/356 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.019); called by muse, mutect2
- KDR | c.2239A>T p.K747* | Nonsense Mutation (SNP) | VAF 32/519 reads (6%) | called by muse, mutect2
- KIAA1755 | c.386G>T p.C129F | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- KIR3DL1 | c.313G>A p.G105R | Missense Mutation (SNP) | VAF 9/177 reads (5%) | SIFT tolerated (0.52); PolyPhen benign (0.013); called by muse, mutect2
- KLHL34 | c.435C>A p.H145Q | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- KLK5 | c.192C>A p.S64R | Missense Mutation (SNP) | VAF 42/452 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.578); called by muse, mutect2
- LGALS9 | c.779C>T p.S260F (on ENST00000395473 / NM_009587.3; = p.S228F on NM_002308.4) | Missense Mutation (SNP) | VAF 18/364 reads (5%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.997); called by muse, mutect2
- LIPI | c.966T>A p.G322= | Splice Region (SNP) | VAF 7/102 reads (7%) | called by muse, mutect2
- LRIT1 | c.1791G>T p.R597S | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- LRIT2 | c.1321C>A p.H441N | Missense Mutation (SNP) | VAF 20/358 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2
- LRRTM1 | c.851C>A p.S284Y | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- MACF1 | c.53G>T p.R18L | Missense Mutation (SNP) | VAF 35/478 reads (7%) | called by muse, mutect2
- MAGEA12 | c.590C>A p.P197H | Missense Mutation (SNP) | VAF 43/407 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MTNR1B | c.362G>T p.G121V | Missense Mutation (SNP) | VAF 59/542 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.842); called by muse, mutect2
- MYH2 | c.4850C>A p.A1617D | Missense Mutation (SNP) | VAF 29/413 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- MYH8 | c.2532G>T p.K844N | Missense Mutation (SNP) | VAF 18/320 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2
- MYT1 | c.841G>C p.E281Q | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.043); called by muse, mutect2
- MYT1 | c.2632G>T p.V878L | Missense Mutation (SNP) | VAF 20/296 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2
- NAA25 | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.027); called by muse, mutect2
- NKAIN4 | c.415G>T p.A139S | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- NLRP2 | c.659C>A p.T220N | Missense Mutation (SNP) | VAF 24/388 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- NLRP3 | c.145C>A p.H49N | Missense Mutation (SNP) | VAF 100/601 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- NPAS4 | c.830A>C p.Q277P | Missense Mutation (SNP) | VAF 24/280 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.173); called by muse, mutect2
- NUDT11 | c.283G>A p.V95M | Missense Mutation (SNP) | VAF 32/738 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- NUP210L | c.961G>A p.V321M | Missense Mutation (SNP) | VAF 38/375 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR4D10 | c.355G>T p.A119S | Missense Mutation (SNP) | VAF 21/177 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR5R1 | c.824C>G p.S275C | Missense Mutation (SNP) | VAF 19/205 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- OTOS | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- PBXIP1 | c.1949G>T p.R650L | Missense Mutation (SNP) | VAF 34/342 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.69); called by muse, mutect2
- PCDHB12 | c.1168C>A p.P390T | Missense Mutation (SNP) | VAF 27/448 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- PCDHGA12 | c.757G>T p.E253* | Nonsense Mutation (SNP) | VAF 24/162 reads (15%) | called by muse, mutect2, varscan2
- PIEZO2 | c.6299G>T p.G2100V | Missense Mutation (SNP) | VAF 16/384 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- PIEZO2 | c.769T>C p.W257R | Missense Mutation (SNP) | VAF 35/405 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- PIKFYVE | c.5246G>T p.G1749V | Missense Mutation (SNP) | VAF 38/404 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); called by muse, mutect2
- PLB1 | c.1166C>A p.A389D | Missense Mutation (SNP) | VAF 26/428 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.306); called by muse, mutect2
- POU3F4 | c.473C>A p.S158Y | Missense Mutation (SNP) | VAF 12/233 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.048); called by muse, mutect2
- PPP1R32 | c.1118G>T p.G373V | Missense Mutation (SNP) | VAF 14/233 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.16); called by muse, mutect2
- PPTC7 | c.859G>T p.G287* | Nonsense Mutation (SNP) | VAF 14/228 reads (6%) | called by muse, mutect2
- PRKAR1A | c.304G>T p.A102S | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.534); called by muse, mutect2
- PRLHR | c.221G>A p.G74E | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by mutect2, varscan2
- PRODH2 | c.1142G>T p.G381V (on ENST00000301175; = p.G305V on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/426 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRRT2 | c.284C>G p.S95* | Nonsense Mutation (SNP) | VAF 26/493 reads (5%) | called by muse, mutect2
- PSENEN | c.62-1G>T p.X21_splice | Splice Site (SNP) | VAF 37/523 reads (7%) | called by muse, mutect2
- RAB30 | c.302C>G p.P101R | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.991); called by muse, mutect2
- RBP3 | c.25A>T p.M9L | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- RELN | c.6828T>G p.I2276M | Missense Mutation (SNP) | VAF 34/546 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); called by muse, mutect2
- REPS2 | c.1328A>G p.D443G | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2
- RFX8 | c.306G>T p.M102I (on ENST00000646446; = p.M31I on NM_001145664.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2
- RGS22 | c.509T>A p.V170E | Missense Mutation (SNP) | VAF 22/324 reads (7%) | SIFT tolerated (0.94); PolyPhen benign (0.006); called by muse, mutect2
- RHOBTB3 | c.1728A>T p.E576D | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- RIMS2 | c.305A>T p.D102V | Missense Mutation (SNP) | VAF 38/531 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RLIM | c.1756C>A p.L586I | Missense Mutation (SNP) | VAF 12/310 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RNF165 | c.571C>A p.P191T | Missense Mutation (SNP) | VAF 42/459 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); called by muse, mutect2
- SCN8A | c.3206G>A p.G1069D | Missense Mutation (SNP) | VAF 22/366 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2
- SEC24D | c.212A>G p.Q71R | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SH3TC2 | c.2104C>T p.Q702* | Nonsense Mutation (SNP) | VAF 44/738 reads (6%) | called by muse, mutect2
- SLC10A1 | c.191C>A p.A64D | Missense Mutation (SNP) | VAF 36/394 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC18A1 | c.1505A>T p.Y502F | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2
- SLC25A48 | c.283C>A p.P95T | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLC25A51 | c.49T>G p.S17A | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC8A3 | c.142T>A p.C48S | Missense Mutation (SNP) | VAF 38/438 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.661); called by muse, mutect2
- SLC9A2 | c.1250A>T p.N417I | Missense Mutation (SNP) | VAF 22/296 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SMS | c.382G>T p.D128Y | Missense Mutation (SNP) | VAF 20/566 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- SOX11 | c.898G>T p.G300C | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); called by muse, mutect2
- SPATA13 | c.1922G>T p.W641L | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.082); called by muse, mutect2
- SPATA13 | c.1923G>T p.W641C | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- STARD9 | c.2416C>G p.P806A | Missense Mutation (SNP) | VAF 26/470 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.341); called by muse, mutect2
- SYDE2 | c.911A>C p.E304A | Missense Mutation (SNP) | VAF 16/159 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- TBX3 | c.1245C>A p.H415Q (on ENST00000257566 / NM_016569.4; = p.H395Q on NM_005996.4) | Missense Mutation (SNP) | VAF 25/263 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- TEX51 | c.96C>A p.D32E | Missense Mutation (SNP) | VAF 14/252 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TMEM121B | c.1117G>T p.A373S | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.056); called by muse, mutect2
- TPO | c.1252G>T p.A418S | Missense Mutation (SNP) | VAF 26/318 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- TPO | c.1835C>A p.A612D | Missense Mutation (SNP) | VAF 18/289 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.843); called by muse, mutect2
- TRIM16 | c.1486G>T p.G496W | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRPM2 | c.2603G>T p.W868L | Missense Mutation (SNP) | VAF 23/393 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- TTBK2 | c.721A>T p.R241* | Nonsense Mutation (SNP) | VAF 14/200 reads (7%) | called by muse, mutect2
- TTI1 | c.376G>A p.G126R | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.693); called by muse, mutect2
- UGT1A5 | c.842G>T p.C281F | Missense Mutation (SNP) | VAF 33/340 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- UNC5D | c.407G>T p.C136F | Missense Mutation (SNP) | VAF 19/362 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- VN1R2 | c.236C>G p.A79G | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VN1R5 | c.954G>T p.L318F | Missense Mutation (SNP) | VAF 28/286 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.421); called by muse, mutect2
- VWA5B2 | c.2057C>A p.S686Y | Missense Mutation (SNP) | VAF 27/201 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- WDR93 | c.475A>G p.I159V | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.12); called by muse, mutect2
- XIRP2 | c.9166G>T p.G3056C (on ENST00000628543; = p.G3231C on NM_152381.6) | Missense Mutation (SNP) | VAF 20/320 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); called by muse, mutect2
- XKR5 | c.548A>T p.Q183L | Missense Mutation (SNP) | VAF 35/517 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.159); called by muse, mutect2
- ZFHX4 | c.3413C>G p.A1138G | Missense Mutation (SNP) | VAF 14/175 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.015); called by muse, mutect2
- ZFPM2 | c.2966C>T p.P989L | Missense Mutation (SNP) | VAF 14/239 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); called by muse, mutect2
- ZIC3 | c.307A>G p.S103G | Missense Mutation (SNP) | VAF 18/333 reads (5%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.914); called by muse, mutect2
- ZNF782 | c.681G>T p.K227N | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.019); called by mutect2, varscan2
- ZNF804A | c.208C>A p.Q70K | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- ZP4 | c.940C>A p.P314T | Missense Mutation (SNP) | VAF 42/272 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- ACAD9 | c.282A>T p.P94= | Silent (SNP) | VAF 14/232 reads (6%) | called by muse, mutect2
- ADGRB3 | c.1251G>T p.S417= | Silent (SNP) | VAF 22/304 reads (7%) | catalogued as COSV65390770; called by muse, mutect2
- ALOX15 | c.1302C>A p.A434= | Silent (SNP) | VAF 10/175 reads (6%) | called by muse, mutect2
- ARHGEF10L | c.1149C>T p.R383= | Silent (SNP) | VAF 34/342 reads (10%) | catalogued as rs115978067; called by muse, mutect2
- ARHGEF11 | c.4251G>A p.L1417= | Silent (SNP) | VAF 28/188 reads (15%) | called by muse, mutect2, varscan2
- ASTN2 | c.3576G>T p.L1192= (on ENST00000313400 / NM_001365069.1; = p.L1141= on NM_014010.5) | Silent (SNP) | VAF 32/526 reads (6%) | called by muse, mutect2
- AZU1 | c.177C>A p.A59= | Silent (SNP) | VAF 7/52 reads (13%) | called by muse, mutect2
- BLK | c.594C>A p.L198= | Silent (SNP) | VAF 12/216 reads (6%) | called by muse, mutect2
- CADPS | c.1794G>A p.E598= | Silent (SNP) | VAF 15/277 reads (5%) | catalogued as rs1170196303; called by muse, mutect2
- CEP350 | c.171G>C p.V57= | Silent (SNP) | VAF 14/162 reads (9%) | called by muse, mutect2
- CES1 | c.957G>T p.L319= | Silent (SNP) | VAF 22/312 reads (7%) | called by muse, mutect2
- CLEC4F | c.900C>A p.S300= | Silent (SNP) | VAF 17/233 reads (7%) | catalogued as COSV55478752; called by muse, mutect2
- CNOT1 | c.3240G>A p.V1080= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as rs1218706720; called by muse, mutect2
- CSMD2 | c.10314C>A p.P3438= | Silent (SNP) | VAF 14/162 reads (9%) | called by muse, mutect2
- DAOA | c.318C>T p.F106= | Silent (SNP) | VAF 18/332 reads (5%) | called by muse, mutect2
- DCDC1 | c.4545T>A p.S1515= (on ENST00000597505 / NM_001367979.1; = p.S622= on NM_020869.3) | Silent (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- DLX1 | c.75G>A p.P25= | Silent (SNP) | VAF 24/284 reads (8%) | called by muse, mutect2
- DNAH9 | c.7476G>T p.L2492= | Silent (SNP) | VAF 36/440 reads (8%) | called by muse, mutect2
- FSHR | c.1629G>C p.V543= | Silent (SNP) | VAF 14/294 reads (5%) | called by muse, mutect2
- FSHR | c.1503C>A p.A501= | Silent (SNP) | VAF 16/248 reads (6%) | catalogued as COSV100438010; called by muse, mutect2
- GCN1 | c.1788G>T p.G596= | Silent (SNP) | VAF 14/222 reads (6%) | called by muse, mutect2
- GNAS | c.681G>A p.E227= | Silent (SNP) | VAF 46/698 reads (7%) | catalogued as rs1185580281; called by muse, mutect2
- GPKOW | c.1329G>T p.R443= | Silent (SNP) | VAF 16/366 reads (4%) | called by muse, mutect2
- GPR32 | c.783G>A p.L261= | Silent (SNP) | VAF 26/266 reads (10%) | called by muse, mutect2
- GRIPAP1 | c.1827T>G p.A609= | Silent (SNP) | VAF 14/265 reads (5%) | called by muse, mutect2
- HEPHL1 | c.984C>A p.A328= | Silent (SNP) | VAF 47/389 reads (12%) | called by muse, mutect2, varscan2
- HIVEP3 | c.2763C>T p.S921= | Silent (SNP) | VAF 30/412 reads (7%) | called by muse, mutect2
- IGLON5 | c.414C>A p.I138= | Silent (SNP) | VAF 28/392 reads (7%) | called by muse, mutect2
- ITGA2B | c.522C>T p.Y174= | Silent (SNP) | VAF 23/160 reads (14%) | called by muse, mutect2, varscan2
- KIR3DL3 | c.846G>A p.L282= | Silent (SNP) | VAF 20/225 reads (9%) | called by muse, mutect2
- MICAL3 | c.2874G>C p.L958= | Silent (SNP) | VAF 48/561 reads (9%) | catalogued as rs1229585539; called by muse, mutect2
- MROH9 | c.1296C>T p.F432= | Silent (SNP) | VAF 24/233 reads (10%) | called by muse, mutect2, varscan2
- NLRP2 | c.660C>A p.T220= | Silent (SNP) | VAF 24/390 reads (6%) | called by muse, mutect2
- NPSR1 | c.1047C>A p.L349= | Silent (SNP) | VAF 16/238 reads (7%) | called by muse, mutect2
- OAS1 | c.703C>T p.L235= | Silent (SNP) | VAF 39/384 reads (10%) | catalogued as COSV99177281; called by muse, mutect2
- PYGM | c.1929C>T p.V643= | Silent (SNP) | VAF 44/572 reads (8%) | catalogued as COSV51215876, COSV51225301; called by muse, mutect2
- RYR2 | c.3921G>T p.P1307= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as COSV63678299, COSV63689105; called by muse, mutect2, varscan2
- SASH1 | c.1890A>T p.G630= | Silent (SNP) | VAF 18/338 reads (5%) | called by muse, mutect2
- SYTL5 | c.1368C>A p.S456= | Silent (SNP) | VAF 21/303 reads (7%) | called by muse, mutect2
- TDRD6 | c.333G>T p.S111= | Silent (SNP) | VAF 10/109 reads (9%) | called by muse, mutect2
- TDRD6 | c.507C>T p.C169= | Silent (SNP) | VAF 13/185 reads (7%) | called by muse, mutect2
- TMEM130 | c.750C>A p.P250= | Silent (SNP) | VAF 9/135 reads (7%) | called by muse, mutect2
- UBQLN2 | c.1611T>G p.T537= | Silent (SNP) | VAF 17/343 reads (5%) | called by muse, mutect2
- UBXN4 | c.1050A>G p.A350= | Silent (SNP) | VAF 10/106 reads (9%) | called by muse, mutect2
- UGT2B7 | c.639T>C p.N213= | Silent (SNP) | VAF 7/98 reads (7%) | called by muse, mutect2
- WASHC2A | c.2916G>T p.A972= | Silent (SNP) | VAF 29/642 reads (5%) | called by muse, mutect2
- YPEL4 | c.163C>A p.R55= | Silent (SNP) | VAF 22/402 reads (5%) | called by muse, mutect2
- ZAN | c.2886C>A p.P962= | Silent (SNP) | VAF 85/613 reads (14%) | called by muse, mutect2, varscan2
- ZC2HC1B | c.576G>T p.T192= | Silent (SNP) | VAF 24/354 reads (7%) | called by muse, mutect2
- ZEB2 | c.12G>T p.P4= | Silent (SNP) | VAF 56/783 reads (7%) | catalogued as COSV57951221; called by muse, mutect2
- ZFHX4 | c.492G>A p.A164= | Silent (SNP) | VAF 20/246 reads (8%) | catalogued as rs547565895, COSV51068535; called by muse, mutect2
- ZNF121 | c.420A>G p.V140= | Silent (SNP) | VAF 9/96 reads (9%) | called by muse, mutect2
- AL133467.5 | chr14:95663559 C>A | 3'Flank (SNP) | VAF 18/442 reads (4%) | called by muse, mutect2
- ARHGAP40 | c.-102_-101insG | 5'UTR (INS) | VAF 13/128 reads (10%) | called by mutect2, varscan2
- ARHGEF15 | c.601+77G>C | Intron (SNP) | VAF 22/395 reads (6%) | called by muse, mutect2
- ARHGEF4 | chr2:130916103 C>A | 5'Flank (SNP) | VAF 20/200 reads (10%) | called by muse, mutect2
- C12orf76 | n.664+5977C>G | Intron (SNP) | VAF 29/363 reads (8%) | called by muse, mutect2
- CPLANE1 | c.*3461G>A | 3'UTR (SNP) | VAF 16/383 reads (4%) | called by muse, mutect2
- CSMD3 | c.178+59889G>T | Intron (SNP) | VAF 49/756 reads (6%) | called by muse, mutect2
- DCHS2 | n.4132G>A | RNA (SNP) | VAF 8/85 reads (9%) | called by muse, mutect2
- EPSTI1 | chr13:42888372 G>C | 3'Flank (SNP) | VAF 24/490 reads (5%) | called by muse, mutect2
- HLA-DMB | c.776-49G>T | Intron (SNP) | VAF 9/170 reads (5%) | called by muse, mutect2
- IGHMBP2 | c.711+43C>T | Intron (SNP) | VAF 26/398 reads (7%) | called by muse, mutect2
- KIRREL3 | c.55+5139C>A | Intron (SNP) | VAF 49/313 reads (16%) | called by muse, mutect2, varscan2
- KRTDAP | c.*19G>T | 3'UTR (SNP) | VAF 38/537 reads (7%) | called by muse, mutect2
- LYZL6 | c.*14T>A | 3'UTR (SNP) | VAF 12/171 reads (7%) | called by muse, mutect2
- MIR7162 | chr10:30365247 C>A | 3'Flank (SNP) | VAF 12/260 reads (5%) | called by muse, mutect2
- MYOCOS | c.*43A>T | 3'UTR (SNP) | VAF 24/204 reads (12%) | called by muse, mutect2, varscan2
- NSMCE1 | c.137-6547A>G | Intron (SNP) | VAF 7/117 reads (6%) | called by muse, mutect2
- OFCC1 | n.1806T>A | RNA (SNP) | VAF 18/342 reads (5%) | called by muse, mutect2
- PAMR1 | c.-7G>T | 5'UTR (SNP) | VAF 17/183 reads (9%) | called by muse, mutect2
- PDE6A | c.1473+48A>T | Intron (SNP) | VAF 20/286 reads (7%) | called by muse, mutect2
- PLD3 | c.-55C>G | 5'UTR (SNP) | VAF 24/393 reads (6%) | called by muse, mutect2
- PLEKHG3 | chr14:64749267 T>A | 3'Flank (SNP) | VAF 36/404 reads (9%) | called by muse, mutect2
- PNO1 | chr2:68157797 G>T | 5'Flank (SNP) | VAF 4/38 reads (11%) | catalogued as rs1473892853; called by muse, varscan2
- PSMD4 | c.-35C>T | 5'UTR (SNP) | VAF 30/320 reads (9%) | called by muse, mutect2, varscan2
- PUDP | c.511-7251G>T | Intron (SNP) | VAF 18/254 reads (7%) | called by muse, mutect2
- RNF40 | c.*909G>T | 3'UTR (SNP) | VAF 14/272 reads (5%) | called by muse, mutect2
- ROBO4 | c.-14G>T | 5'UTR (SNP) | VAF 12/74 reads (16%) | called by muse, mutect2, varscan2
- TBX22 | c.175+41C>A | Intron (SNP) | VAF 22/312 reads (7%) | called by muse, mutect2
- TNNC1 | c.*47G>T | 3'UTR (SNP) | VAF 24/290 reads (8%) | called by muse, mutect2
- USH1C | c.37-11G>T | Intron (SNP) | VAF 40/478 reads (8%) | called by muse, mutect2
- ZEB2 | chr2:144520108 C>A | 5'Flank (SNP) | VAF 48/684 reads (7%) | called by muse, mutect2
